Somatic mutation profile of tumor specimen TCGA-95-7567-01A (aliquot TCGA-95-7567-01A-11D-2063-08) from TCGA case TCGA-95-7567, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 61.4 years (22,437 days).
Specimen TCGA-95-7567-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04b06599-0300-4e8e-bffb-72cf5825791d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-95-7567-10A (Blood Derived Normal), aliquot TCGA-95-7567-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eaba4756-5b04-49d8-be3d-b9b9fea147cb

The open-access MAF lists 1,002 somatic variants for this specimen: 756 protein-altering or splice-affecting, 228 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 626, Silent 228, Frame Shift Ins 41, Nonsense Mutation 37, Splice Site 22, Frame Shift Del 15, Splice Region 12, Intron 6, 5'Flank 4, RNA 4, 3'UTR 3, Nonstop Mutation 2.

Variants (750 of 1,002; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYO15A | c.1185dup p.E396Rfs*36 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs1057520008, CD100447, COSV52760580, COSV52806341, COSV52877975, COSV52979708; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AASDH | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV99221781; called by muse, mutect2, varscan2
- ABCA13 | c.9445C>A p.P3149T | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101447176, COSV71285151; called by muse, mutect2, varscan2
- ABCA6 | c.3867G>T p.Q1289H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV99447564; called by muse, mutect2, varscan2
- ABCB1 | c.667C>A p.P223T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV55966863, COSV99714182; called by muse, mutect2, varscan2
- ABCC1 | c.3485T>C p.V1162A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.506); catalogued as COSV100580268; called by muse, mutect2, varscan2
- ABCC8 | c.2737C>A p.L913I | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as COSV100217676, COSV56846017; called by muse, mutect2, varscan2
- ABCF1 | c.1759C>T p.R587* (on ENST00000326195 / NM_001025091.2; = p.R549* on NM_001090.3) | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as rs778244915, COSV100401034; called by muse, mutect2, varscan2
- ABCF2 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV55181500, COSV99734827; called by muse, mutect2, varscan2
- ABL1 | c.2732G>T p.G911V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.953); catalogued as COSV100584525; called by muse, mutect2, varscan2
- AC097636.1 | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV101469690; called by muse, mutect2
- ACAD9 | c.1064T>C p.V355A | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV100459404; called by muse, mutect2, varscan2
- ACOXL | c.1093A>C p.K365Q | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV101095871; called by muse, mutect2, varscan2
- ACSM5 | c.1297A>G p.N433D | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as rs1432893686, COSV100089488; called by muse, mutect2, varscan2
- ACTB | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs11546912, COSV59320776; called by muse, mutect2
- ADAM29 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV63669764; called by muse, mutect2
- ADAMTS12 | c.4041C>G p.D1347E | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100711596; called by muse, mutect2, varscan2
- ADAMTS9 | c.4018-1G>A p.X1340_splice | Splice Site (SNP) | VAF 17/50 reads (34%) | catalogued as COSV99900103; called by muse, mutect2, varscan2
- ADAMTSL2 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100618926, COSV100619026; called by muse, mutect2, varscan2
- ADAR | c.3665A>G p.Y1222C | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV99426645; called by muse, mutect2, varscan2
- ADARB2 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101187241; called by muse, mutect2, varscan2
- ADGRA2 | c.1573dup p.A525Gfs*59 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs760256806; called by mutect2, varscan2
- ADGRF4 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 74/131 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1369026730, COSV99348888; called by muse, mutect2, varscan2
- ADGRF5 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99346348; called by muse, mutect2, varscan2
- ADGRL2 | c.1175T>C p.F392S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99591257; called by muse, mutect2, varscan2
- ADORA1 | c.632T>G p.L211R | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99704710; called by muse, mutect2
- ADPGK | c.745A>G p.S249G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV100295364; called by muse, mutect2, varscan2
- ADRA1B | c.130A>G p.R44G | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV100140420; called by muse, mutect2, varscan2
- AFF2 | c.1042-2A>G p.X348_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99665961; called by muse, mutect2, varscan2
- AFF2 | c.3763C>T p.R1255W | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782758944, COSV53993153; called by muse, mutect2, varscan2
- AGA | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99219694; called by muse, mutect2, varscan2
- AGGF1 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100462191; called by mutect2, varscan2
- AGXT | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100280329; called by muse, mutect2, varscan2
- AIP | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as rs775563618, COSV99653547; called by muse, varscan2
- AKAP11 | c.1525A>T p.T509S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV99214294; called by muse, mutect2, varscan2
- AKAP6 | c.1892T>C p.L631P | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99804071; called by muse, mutect2
- ALS2 | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99969989; called by muse, mutect2, varscan2
- ANGEL2 | c.165G>T p.M55I | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV100853990; called by muse, mutect2
- ANK2 | c.8920G>T p.A2974S | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.014); catalogued as COSV100003899, COSV52160174; called by muse, varscan2
- ANKIB1 | c.2197G>C p.A733P | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV99729860; called by muse, mutect2, varscan2
- ANKRD11 | c.7261G>A p.A2421T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as rs370897874; called by muse, mutect2
- ANKRD30A | c.2623G>T p.E875* (on ENST00000611781; = p.E819* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 65/216 reads (30%) | catalogued as COSV100653771, COSV100654359; called by muse, mutect2, varscan2
- ANO7 | c.36A>T p.Q12H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV99239310; called by muse, mutect2, varscan2
- ANXA9 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100929164; called by muse, mutect2
- AOX1 | c.2794A>G p.T932A | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs745912681, COSV101022214; called by muse, mutect2, varscan2
- APOA4 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100759355, COSV100759392; called by muse, mutect2, varscan2
- APOB | c.10706A>C p.N3569T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as CD084831, COSV99267673; called by muse, mutect2, varscan2
- APOBEC4 | c.950T>C p.V317A | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV100426177; called by muse, mutect2, varscan2
- APOC1 | c.113A>G p.K38R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV99377242; called by muse, mutect2, varscan2
- ARHGAP24 | c.1758dup p.N587Efs*3 (on ENST00000395184 / NM_001025616.3; = p.N494Efs*3 on NM_031305.3) | Frame Shift Ins (INS) | VAF 16/69 reads (23%) | catalogued as rs1196259804; called by mutect2, pindel, varscan2
- ARHGAP35 | c.2347C>T p.R783* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | catalogued as COSV68330848; called by muse, mutect2
- ARHGEF11 | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs140673049; called by muse, mutect2, varscan2
- ARMC6 | c.409T>C p.Y137H (on ENST00000392336; = p.Y112H on NM_033415.4) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.496); catalogued as COSV99523155; called by muse, mutect2, varscan2
- ASB18 | c.1334C>A p.P445H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100430800; called by muse, mutect2, varscan2
- ASCC3 | c.5218G>A p.A1740T | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV100976860; called by muse, mutect2, varscan2
- ASPM | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as rs1557967531, COSV99661006; called by muse, mutect2, varscan2
- ASTN1 | c.2198A>G p.N733S | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV99922898; called by muse, mutect2, varscan2
- ASXL3 | c.1862C>G p.A621G | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV99326331; called by muse, mutect2, varscan2
- ATAD2 | c.825T>A p.D275E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs149531312; called by muse, mutect2, varscan2
- ATM | c.5917A>G p.R1973G | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as rs786202089, COSV53748463, COSV99591664; ClinVar: uncertain significance; called by muse, mutect2
- ATP11B | c.2729G>A p.S910N | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV100018067; called by muse, mutect2, varscan2
- ATP2B3 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs1042544082, COSV99685664; called by muse, mutect2, varscan2
- ATP2B3 | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs782166942, COSV99685688; called by muse, mutect2
- ATP6V1B1 | c.1146C>A p.I382= | Splice Region (SNP) | VAF 11/65 reads (17%) | catalogued as rs781862317, COSV99314461; called by muse, mutect2, varscan2
- ATP7A | c.3182T>C p.V1061A | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100431593; called by muse, mutect2, varscan2
- ATP8B1 | c.1808T>C p.M603T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99377799; called by muse, mutect2
- ATXN1 | c.1736T>C p.I579T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99787578; called by muse, mutect2, varscan2
- AXIN1 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs200996293, COSV51987145; called by muse, mutect2, varscan2
- BAIAP2L2 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs554528952, COSV100140704; called by muse, mutect2, varscan2
- BBOX1 | c.218dup p.V74Gfs*8 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | catalogued as rs1157195022; called by pindel, varscan2
- BCKDHB | c.758T>A p.I253K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV100244034; called by mutect2, varscan2
- BIVM-ERCC5 | c.2875A>C p.S959R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.118); catalogued as COSV100863921; called by muse, mutect2, varscan2
- BMPR1B | c.727A>T p.R243* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99216228; called by muse, mutect2, varscan2
- BOD1L1 | c.439T>A p.F147I | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99240259; called by muse, mutect2, varscan2
- BPTF | c.1948A>G p.S650G | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1049437765, COSV100075923; called by muse, mutect2, varscan2
- BRAP | c.1730dup p.S578Qfs*51 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | catalogued as rs1184461495; called by mutect2, pindel, varscan2
- BRSK2 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV100373111; called by muse, mutect2
- BRWD3 | c.1260G>T p.K420N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV100956462; called by muse, mutect2, varscan2
- BTBD2 | c.1234A>C p.I412L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV99724950; called by muse, mutect2, varscan2
- BZW2 | c.1157A>G p.H386R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99334853; called by muse, mutect2, varscan2
- C1QL1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99492838; called by muse, mutect2, varscan2
- C2CD3 | c.5131G>T p.V1711F | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100487321; called by muse, mutect2, varscan2
- C2orf16 | c.2545C>T p.R849* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as rs778814464, COSV100820977; called by muse, mutect2, varscan2
- C5orf34 | c.1597A>G p.T533A | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV100175589; called by muse, mutect2, varscan2
- C7orf33 | c.350G>C p.R117T | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as COSV100188910; called by muse, mutect2, varscan2
- C7orf57 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs367644498; called by muse, mutect2, varscan2
- C9orf131 | c.2320A>G p.T774A | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100398278; called by muse, mutect2, varscan2
- CACNB2 | c.194C>G p.S65* (on ENST00000324631 / NM_201596.3; = p.S37* on NM_201571.4) | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as COSV56635779, COSV99996190; called by muse, mutect2, varscan2
- CALCR | c.510C>A p.F170L | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV64008363; called by muse, mutect2, varscan2
- CALCR | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV64007902; called by muse, varscan2
- CASP4 | c.1037T>C p.V346A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101274211; called by muse, mutect2
- CCDC158 | c.2215A>G p.K739E | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101187357; called by muse, mutect2, varscan2
- CCDC172 | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV60937372; called by muse, mutect2, varscan2
- CCDC80 | c.2762A>G p.Y921C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99245243; called by muse, mutect2, varscan2
- CCER1 | c.869A>C p.Y290S | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.069); catalogued as COSV100727146; called by muse, mutect2, varscan2
- CD163 | c.1767G>T p.K589N | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV100775599; called by muse, mutect2
- CD163L1 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100550608; called by muse, mutect2, varscan2
- CD1E | c.1049T>C p.M350T | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781038011, COSV100937060; called by muse, mutect2, varscan2
- CD200 | c.571C>A p.P191T (on ENST00000473539 / NM_001004196.3; = p.P166T on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100238472, COSV59863350; called by muse, mutect2, varscan2
- CDADC1 | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV51913238; called by mutect2, varscan2
- CDC40 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.848); catalogued as rs1474439696, COSV100309553; called by muse, mutect2, varscan2
- CDC42EP4 | c.282G>T p.R94S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100231977; called by muse, mutect2, varscan2
- CDH1 | c.1009_1010del p.X337_splice | Splice Site (DEL) | VAF 12/70 reads (17%) | catalogued as rs786201045; called by pindel, varscan2
- CDH10 | c.1360T>C p.W454R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV100052940; called by mutect2, varscan2
- CDH23 | c.5468C>A p.A1823D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99823503; called by muse, mutect2, varscan2
- CELF2 | c.1307A>G p.D436G (on ENST00000416382 / NM_001025077.3; = p.D449G on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258246; called by muse, mutect2, varscan2
- CELSR3 | c.8488T>G p.S2830A | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.675); catalogued as COSV99374815; called by muse, mutect2, varscan2
- CELSR3 | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746648692, COSV99374818; called by muse, mutect2, varscan2
- CERKL | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV100184127; called by muse, mutect2, varscan2
- CERS6 | c.587A>G p.Q196R | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99987658; called by muse, mutect2, varscan2
- CFAP251 | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV99945767; called by muse, mutect2
- CHD6 | c.3818C>T p.P1273L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100498643; called by muse, mutect2, varscan2
- CHEK1 | c.1337G>A p.G446D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54025198; called by muse, mutect2
- CIART | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV99290420; called by muse, mutect2, varscan2
- CLCN3 | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as COSV100641817; called by muse, mutect2, varscan2
- CLEC18B | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100376126, COSV60577540; called by muse, mutect2
- CLK3 | c.1460A>G p.H487R (on ENST00000395066 / NM_001130028.1; = p.H339R on NM_003992.4) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100166140; called by muse, mutect2, varscan2
- CLRN1 | c.287G>A p.S96N (on ENST00000327047 / NM_174878.3; = p.S20N on NM_052995.2) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); catalogued as rs767244695, COSV99902654; called by muse, varscan2
- CLTC | c.176G>A p.S59N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99292820; called by muse, mutect2, varscan2
- CLTC | c.681G>T p.K227N | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99292823; called by muse, mutect2, varscan2
- CLUH | c.1405A>G p.T469A (on ENST00000435359; = p.T507A on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1382687884, COSV101425872; called by muse, mutect2, varscan2
- CLVS1 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV100370599; called by muse, mutect2
- CNOT2 | c.409A>G p.R137G | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV57504331, COSV57504579; called by muse, mutect2, varscan2
- CNOT3 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99652296; called by muse, mutect2, varscan2
- CNTF | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV100284721; called by muse, mutect2, varscan2
- CNTN4 | c.2531A>G p.E844G | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100639664; called by muse, mutect2
- CNTN5 | c.3119T>A p.V1040D | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.494); catalogued as COSV99680785; called by muse, mutect2, varscan2
- CNTN6 | c.2192G>T p.G731V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100611758; called by muse, mutect2, varscan2
- CNTNAP5 | c.2748A>T p.V916= | Splice Region (SNP) | VAF 25/85 reads (29%) | catalogued as COSV101444164; called by muse, mutect2, varscan2
- COL11A1 | c.3722C>A p.P1241H | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100617927; called by muse, mutect2, varscan2
- COL16A1 | c.4303A>C p.N1435H | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99593540, COSV99595323; called by muse, mutect2, varscan2
- COL22A1 | c.3997G>A p.G1333R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051744139, COSV100280550; called by mutect2, varscan2
- COL4A1 | c.3386C>A p.P1129H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101011521; called by muse, mutect2, varscan2
- COL4A6 | c.3691C>T p.R1231* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as COSV57861982; called by muse, mutect2, varscan2
- COL6A3 | c.8107A>C p.S2703R | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.927); catalogued as COSV99800988; called by muse, mutect2, varscan2
- COL9A3 | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751668107, COSV59654792, COSV59655641; called by muse, mutect2, varscan2
- COMT | c.275T>G p.V92G | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99258855; called by muse, mutect2, varscan2
- COQ8B | c.368-1G>C p.X123_splice | Splice Site (SNP) | VAF 13/59 reads (22%) | catalogued as rs1201048143, COSV99699600; called by muse, mutect2, varscan2
- CPN2 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.42); catalogued as COSV100103234; called by muse, mutect2
- CPNE7 | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1481938041, COSV99255103; called by muse, mutect2, varscan2
- CPO | c.34G>T p.G12W | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV99786635; called by muse, mutect2, varscan2
- CPS1 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99243963; called by muse, mutect2, varscan2
- CPSF3 | c.1281G>C p.L427F | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99433287; called by muse, mutect2
- CR1 | c.3340T>C p.Y1114H | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as rs1262658729, COSV100888009; called by muse, mutect2, varscan2
- CREBBP | c.7058G>T p.R2353L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as COSV99271720; called by muse, mutect2, varscan2
- CSMD1 | c.8185G>T p.G2729* (on ENST00000520002; = p.G2728* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 30/109 reads (28%) | catalogued as COSV100153115; called by muse, mutect2, varscan2
- CSMD1 | c.6450C>A p.N2150K (on ENST00000520002; = p.N2149K on NM_033225.6) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100148623, COSV100153116; called by muse, mutect2, varscan2
- CSMD3 | c.9251C>A p.T3084N (on ENST00000297405 / NM_001363185.1; = p.T2915N on NM_052900.3) | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0.197); catalogued as COSV99846193; called by muse, mutect2, varscan2
- CSMD3 | c.8983T>A p.C2995S (on ENST00000297405 / NM_001363185.1; = p.C2826S on NM_052900.3) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99846195; called by muse, mutect2, varscan2
- CSMD3 | c.5650C>G p.P1884A (on ENST00000297405 / NM_001363185.1; = p.P1780A on NM_052900.3) | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV99846199; called by muse, mutect2, varscan2
- CSMD3 | c.3303T>A p.H1101Q (on ENST00000297405 / NM_001363185.1; = p.H997Q on NM_052900.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV52204100, COSV99846202; called by muse, mutect2, varscan2
- CSMD3 | c.2768G>A p.W923* (on ENST00000297405 / NM_001363185.1; = p.W819* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV52196052, COSV99846207; called by muse, mutect2, varscan2
- CSPP1 | c.2217T>G p.D739E (on ENST00000676605; = p.D698E on NM_024790.6) | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.755); catalogued as COSV99139760; called by muse, mutect2, varscan2
- CSRP1 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV100384572; called by muse, mutect2, varscan2
- CTNNA2 | c.1847T>A p.V616E | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100561919; called by muse, mutect2
- CTSW | c.791T>C p.I264T | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100327522; called by muse, mutect2, varscan2
- CUBN | c.8248A>G p.R2750G | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as COSV100913440; called by muse, mutect2
- CUX1 | c.491A>T p.K164M (on ENST00000292535 / NM_181552.4; = p.K175M on NM_001913.5) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV99472890; called by muse, varscan2
- CUX1 | c.596G>A p.S199N (on ENST00000292535 / NM_181552.4; = p.S210N on NM_001913.5) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV99472893; called by muse, mutect2, varscan2
- CYP4F3 | c.1124T>C p.L375P | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658636; called by muse, mutect2, varscan2
- CYTH2 | c.977A>G p.Y326C (on ENST00000427476; = p.Y325C on NM_004228.7) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV100287349; called by muse, mutect2, varscan2
- CYYR1 | c.404C>A p.T135N | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV100177538, COSV54828601; called by muse, mutect2, varscan2
- DBF4B | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100154663; called by muse, mutect2, varscan2
- DCDC1 | c.2461G>T p.G821C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV100664122; called by muse, mutect2, varscan2
- DDX27 | c.2093A>G p.E698G | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100872595; called by muse, mutect2, varscan2
- DDX46 | c.2072T>C p.V691A | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844920; called by muse, mutect2, varscan2
- DDX50 | c.640-2A>G p.X214_splice | Splice Site (SNP) | VAF 5/50 reads (10%) | catalogued as COSV101007307; called by muse, mutect2, varscan2
- DDX55 | c.557A>T p.N186I | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99434787; called by muse, mutect2, varscan2
- DDX59 | c.310G>T p.G104W | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100494687, COSV58751947; called by muse, mutect2, varscan2
- DERA | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.738); catalogued as COSV101397497; called by muse, mutect2, varscan2
- DEUP1 | c.751C>A p.L251I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV99977586; called by muse, mutect2, varscan2
- DGCR8 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100708152; called by muse, mutect2, varscan2
- DHTKD1 | c.987+1G>T p.X329_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | catalogued as COSV99536874; called by muse, mutect2, varscan2
- DHX29 | c.3347G>T p.G1116V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99287674; called by muse, mutect2, varscan2
- DICER1 | c.3088A>G p.K1030E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100602511; called by muse, mutect2, varscan2
- DISP3 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53828675, COSV53837760; called by muse, mutect2, varscan2
- DISP3 | c.905A>C p.E302A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99609844; called by muse, mutect2, varscan2
- DLG2 | c.1960G>C p.E654Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV54625070, COSV99719151; called by muse, mutect2, varscan2
- DMRT3 | c.761T>A p.V254E | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51907008; called by muse, mutect2, varscan2
- DNAAF2 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.184); catalogued as rs756765143, COSV100024232; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAAF5 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99860262; called by muse, mutect2, varscan2
- DNAJC25 | c.685A>G p.K229E | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1390326993; called by muse, mutect2
- DNAJC5G | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.511); catalogued as COSV99940638; called by muse, mutect2, varscan2
- DNAL4 | c.101A>C p.E34A | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99326171; called by muse, mutect2, varscan2
- DOCK2 | c.2210T>C p.L737P | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99914997; called by muse, mutect2, varscan2
- DOK6 | c.302A>G p.E101G | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV101234955; called by muse, mutect2, varscan2
- DPH7 | c.841G>T p.V281L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as rs762677167, COSV104374187, COSV99483686; called by muse, mutect2, varscan2
- DPP10 | c.1985A>T p.K662I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.425); catalogued as COSV100071193; called by muse, mutect2, varscan2
- DPT | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100892171; called by muse, mutect2, varscan2
- DPYSL4 | c.1317C>A p.C439* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100063369; called by muse, mutect2, varscan2
- DRD1 | c.785T>A p.M262K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.14); catalogued as COSV101192518, COSV67104719; called by muse, mutect2, varscan2
- DST | c.18446G>T p.R6149L (on ENST00000361203 / NM_001374722.1; = p.R3846L on NM_015548.5) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55041045, COSV99759505; called by muse, mutect2
- DST | c.16164G>T p.Q5388H (on ENST00000361203 / NM_001374722.1; = p.Q2976H on NM_015548.5) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.315); catalogued as COSV99759508; called by muse, mutect2, varscan2
- DSTYK | c.2257A>T p.T753S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.02); catalogued as COSV100904696; called by muse, mutect2, varscan2
- ECHDC3 | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1215234115, COSV101004564; called by muse, mutect2
- EEF1G | c.26A>T p.Y9F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as COSV100240644; called by muse, mutect2, varscan2
- EEF2K | c.1441-2A>C p.X481_splice | Splice Site (SNP) | VAF 8/154 reads (5%) | catalogued as COSV99533614; called by muse, mutect2
- EHMT1 | c.2596G>A p.V866I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.572); catalogued as rs749645029, COSV101509726; ClinVar: benign; called by muse, mutect2, varscan2
- EIF2AK4 | c.2686+1G>A p.X896_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99775323; called by muse, mutect2, varscan2
- EIF3E | c.548A>G p.D183G | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99623487; called by muse, mutect2, varscan2
- ELP2 | c.1315T>C p.Y439H | Missense Mutation (SNP) | VAF 235/278 reads (85%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100627053; called by muse, mutect2, varscan2
- ERBB2 | c.3694dup p.A1232Gfs*45 | Frame Shift Ins (INS) | VAF 7/59 reads (12%) | catalogued as rs768092215; called by mutect2, pindel, varscan2
- ERBB4 | c.2662G>A p.A888T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100727233; called by muse, mutect2, varscan2
- ERCC6L2 | c.1334A>G p.Y445C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV99998960; called by muse, mutect2
- ESPN | c.1111A>T p.S371C | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100911514; called by muse, mutect2, varscan2
- ESYT2 | c.1547A>T p.D516V (on ENST00000613624; = p.D440V on NM_020728.3) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV99277207; called by muse, mutect2, varscan2
- ETNPPL | c.348C>A p.N116K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs377536327, COSV99625625; called by muse, mutect2, varscan2
- EVPL | c.5306G>A p.G1769D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs200465568, COSV101440967; called by mutect2, varscan2
- EXOC2 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.129); catalogued as rs563095350, COSV57867030; called by muse, mutect2, varscan2
- EXPH5 | c.4954G>T p.E1652* | Nonsense Mutation (SNP) | VAF 43/157 reads (27%) | catalogued as COSV99762113; called by muse, mutect2, varscan2
- F9 | c.791C>A p.T264N | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM960589, COSV99496863; called by muse, mutect2, varscan2
- FAM107B | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.042); catalogued as COSV51687544, COSV99474374; called by muse, mutect2, varscan2
- FAM118B | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV100796927; called by muse, mutect2, varscan2
- FAM171B | c.2061C>G p.H687Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100488967; called by muse, mutect2, varscan2
- FAM20B | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV99762613; called by muse, mutect2, varscan2
- FAM234B | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372588047; called by muse, mutect2, varscan2
- FAN1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.129); catalogued as rs137920161, COSV62949859; called by muse, mutect2, varscan2
- FAP | c.693A>G p.I231M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99502505; called by muse, mutect2, varscan2
- FASTKD2 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99379227; called by muse, mutect2, varscan2
- FAT3 | c.423G>T p.W141C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.976); catalogued as COSV99970516; called by muse, mutect2, varscan2
- FAT4 | c.4148A>T p.Q1383L | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.964); catalogued as COSV101272687; called by muse, mutect2, varscan2
- FGF1 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV100532480; called by muse, mutect2, varscan2
- FLG2 | c.2230G>A p.G744S | Missense Mutation (SNP) | VAF 74/543 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as COSV101166168; called by muse, mutect2, varscan2
- FLNC | c.3848C>T p.T1283I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV100368659; called by muse, mutect2, varscan2
- FMN2 | c.193A>T p.K65* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100146979; called by muse, mutect2, varscan2
- FMR1NB | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100789539; called by muse, mutect2
- FRYL | c.6977C>T p.A2326V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.546); catalogued as COSV99977973; called by muse, mutect2, varscan2
- FTSJ3 | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.333); catalogued as COSV100037435; called by muse, mutect2
- FUT9 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1423971943, COSV100134236; called by muse, mutect2
- FYB2 | c.1491del p.R498Gfs*7 | Frame Shift Del (DEL) | VAF 22/99 reads (22%) | catalogued as COSV100599694, COSV58584794; called by mutect2, pindel, varscan2
- FZD10 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as rs748345546, COSV57473741; called by muse, mutect2
- GAB2 | c.562G>A p.A188T (on ENST00000361507 / NM_080491.3; = p.A150T on NM_012296.3) | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.996); catalogued as rs1459019032, COSV100416273; called by muse, mutect2, varscan2
- GABPA | c.943G>T p.G315* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV61396601; called by muse, mutect2, varscan2
- GAK | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100034015; called by muse, mutect2, varscan2
- GALM | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs116100345; called by muse, mutect2, varscan2
- GALNT13 | c.1445T>A p.L482* | Nonsense Mutation (SNP) | VAF 5/75 reads (7%) | catalogued as COSV101224136; called by muse, mutect2
- GALNT3 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101205003; called by muse, mutect2, varscan2
- GDNF | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100427543, COSV58479206; called by muse, mutect2, varscan2
- GIMAP6 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100188376; called by muse, mutect2, varscan2
- GOT1L1 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as COSV100294678; called by muse, mutect2, varscan2
- GPA33 | c.86A>C p.D29A | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV100901253; called by muse, mutect2, varscan2
- GPC6 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.135); catalogued as rs1212629830, COSV100989943; called by muse, varscan2
- GPR176 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as rs150836804; called by muse, mutect2, varscan2
- GPR45 | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99307164; called by muse, mutect2, varscan2
- GPX6 | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100724903; called by muse, mutect2
- GREB1 | c.1787T>C p.V596A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as rs1367169722, COSV99303694; called by muse, mutect2, varscan2
- GRID2 | c.1434A>T p.L478F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99946018; called by muse, mutect2, varscan2
- GRIK5 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs778914367, COSV53474560; called by mutect2, varscan2
- GRIN2D | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99474561; called by muse, mutect2, varscan2
- GSTM1 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100564433; called by muse, mutect2, varscan2
- GSTM2 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs548917973, COSV99598382; called by mutect2, varscan2
- GYG2 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs377090556, COSV100089255; called by muse, mutect2, varscan2
- H6PD | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV101072518; called by muse, mutect2, varscan2
- HACL1 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.06); catalogued as COSV100337367; called by muse, mutect2, varscan2
- HAP1 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV100169945; called by muse, mutect2, varscan2
- HAPLN4 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99364008; called by muse, mutect2, varscan2
- HAT1 | c.256A>C p.M86L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99908095; called by muse, mutect2, varscan2
- HCLS1 | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100101093, COSV57522678; called by muse, mutect2
- HCN1 | c.1645C>A p.R549S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57495992, COSV57527391; called by muse, mutect2, varscan2
- HCRTR2 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100904594; called by muse, mutect2, varscan2
- HDAC2 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs771715712, COSV100892736, COSV64037447; called by muse, mutect2, varscan2
- HELQ | c.1925A>G p.Y642C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766033215, COSV99788093; called by mutect2, varscan2
- HERC4 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as rs766126973, COSV99517402; called by muse, mutect2, varscan2
- HMCN1 | c.12190G>C p.A4064P | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99634907; called by muse, mutect2, varscan2
- HOATZ | c.335A>T p.Q112L | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100239612; called by muse, mutect2
- HOATZ | c.336A>C p.Q112H | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100239614; called by muse, mutect2
- HRH3 | c.1246C>A p.H416N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV100420707; called by muse, mutect2, varscan2
- HSPA1L | c.1901G>A p.G634D | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV100989513; called by muse, mutect2
- HTR6 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.32); catalogued as rs1261252788, COSV57032257; called by muse, mutect2, varscan2
- HYLS1 | c.460T>A p.F154I | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as COSV99700097; called by muse, mutect2
- HYOU1 | c.2459A>C p.E820A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV101345665; called by muse, mutect2, varscan2
- IBTK | c.1258T>A p.W420R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100091407; called by muse, mutect2, varscan2
- IFIT2 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as rs370009481; called by muse, mutect2, varscan2
- IFT52 | c.1136T>G p.L379R | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1171521855, COSV100887668; called by muse, mutect2, varscan2
- IGHV1-58 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 30/96 reads (31%) | catalogued as rs782274668; called by muse, mutect2, varscan2
- IGHV2-70 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs556768737; called by muse, mutect2, varscan2
- IL17REL | c.601+1G>A p.X201_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100377457; called by muse, mutect2, varscan2
- IL1RAP | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.088); catalogued as rs750161003, COSV99300178; called by muse, mutect2, varscan2
- IL1RAPL1 | c.559A>T p.T187S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100150052; called by muse, mutect2, varscan2
- IL23R | c.459C>A p.Y153* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as COSV100724909; called by muse, mutect2, varscan2
- INSC | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.293); catalogued as COSV101089625, COSV65413273; called by muse, mutect2, varscan2
- INSRR | c.3554T>A p.I1185N | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV100948026; called by muse, mutect2, varscan2
- INSRR | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779432741, COSV100947374, COSV63872335; called by muse, mutect2, varscan2
- IPO5 | c.461T>A p.I154N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99847620; called by muse, mutect2, varscan2
- IQGAP1 | c.4478G>T p.R1493L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99185319; called by muse, mutect2, varscan2
- IQGAP1 | c.4696G>A p.A1566T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as COSV99185321; called by muse, mutect2, varscan2
- IRX4 | c.718A>G p.K240E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs932256085, COSV51472406; called by muse, mutect2, varscan2
- ITGA6 | c.2326T>C p.C776R (on ENST00000442250; = p.C737R on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99906024; called by muse, mutect2, varscan2
- ITGA7 | c.3479C>A p.P1160H (on ENST00000555728; = p.P1116H on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99153089; called by muse, mutect2, varscan2
- ITGB6 | c.21C>A p.C7* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | catalogued as COSV99324963; called by muse, mutect2
- ITGB8 | c.653G>C p.C218S | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56011867, COSV99752229; called by muse, mutect2, varscan2
- ITIH5 | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as rs749075587, COSV53667203; called by muse, mutect2
- JHY | c.864G>T p.Q288H | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99913702; called by muse, mutect2, varscan2
- KCNA6 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99768937; called by muse, mutect2, varscan2
- KCNB2 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101578992; called by muse, mutect2
- KCNJ2 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54662939; called by muse, mutect2
- KCNJ8 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV53716565; called by muse, mutect2
- KCNMB1 | c.563C>G p.A188G | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as COSV51131758, COSV99211859; called by muse, mutect2, varscan2
- KCNQ3 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66463886, COSV66469897; called by muse, mutect2, varscan2
- KCNT1 | c.1127C>T p.A376V (on ENST00000488444; = p.A395V on NM_020822.3) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV99706566; called by muse, mutect2, varscan2
- KIAA0586 | c.4022T>C p.M1341T (on ENST00000619416 / NM_001244190.2; = p.M1280T on NM_014749.5) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as rs1188851321, COSV99708814; called by muse, mutect2, varscan2
- KIAA1549 | c.4537A>G p.K1513E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1363744026, COSV99651824; called by muse, mutect2
- KIF17 | c.2693C>A p.P898H | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99929655; called by muse, mutect2, varscan2
- KIF21B | c.2453A>T p.E818V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100145059, COSV59763346; called by muse, mutect2, varscan2
- KIF26B | c.3199dup p.R1067Pfs*50 | Frame Shift Ins (INS) | VAF 8/51 reads (16%) | catalogued as rs1033206065; called by pindel, varscan2
- KIF27 | c.3081G>T p.K1027N | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV99927262, COSV99927501; called by muse, mutect2
- KLHL6 | c.1811T>A p.I604N | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100385005; called by muse, mutect2
- KLHL8 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99911562; called by muse, mutect2, varscan2
- KNTC1 | c.4066G>T p.D1356Y | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV100338744; called by muse, mutect2, varscan2
- KRT17 | c.1189C>A p.Q397K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV100245241; called by muse, mutect2
- KRT38 | c.486A>T p.Q162H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99878367; called by muse, mutect2, varscan2
- KRTAP10-2 | c.79T>C p.C27R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100555334; called by muse, mutect2, varscan2
- KRTAP11-1 | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100190804; called by muse, mutect2, varscan2
- KRTAP6-3 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 15/56 reads (27%) | PolyPhen probably damaging (0.999); catalogued as COSV66963335, COSV99060498; called by muse, mutect2, varscan2
- L1CAM | c.1424T>C p.F475S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as COSV100649446; called by muse, mutect2
- LDB3 | c.233T>A p.L78H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99555844; called by muse, mutect2, varscan2
- LDHAL6B | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV55695851; called by muse, mutect2, varscan2
- LFNG | c.830A>G p.H277R (on ENST00000222725 / NM_001040167.2; = p.H148R on NM_002304.2) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.03); catalogued as COSV99761948; called by muse, mutect2, varscan2
- LGALS1 | c.355A>G p.N119D | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV99313818; called by muse, mutect2, varscan2
- LHX9 | c.713A>G p.D238G | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100436051; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.154C>A p.R52S | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV99524097; called by muse, mutect2
- LINGO4 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV100562085; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LOXL3 | c.774T>A p.C258* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99239919; called by muse, mutect2, varscan2
- LPA | c.4456G>T p.A1486S | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.208); catalogued as COSV100307950; called by muse, mutect2, varscan2
- LRBA | c.6356A>G p.D2119G | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV100462416, COSV58260788; called by muse, mutect2, varscan2
- LRFN2 | c.367C>A p.L123M | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.951); catalogued as COSV100599895; called by muse, mutect2, varscan2
- LRP1 | c.11202dup p.T3735Hfs*32 | Frame Shift Ins (INS) | VAF 7/47 reads (15%) | catalogued as rs1488278211; called by mutect2, pindel, varscan2
- LRP1B | c.10210A>T p.T3404S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV101260225; called by muse, mutect2, varscan2
- LRP1B | c.4114C>A p.L1372I | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101260226; called by muse, mutect2, varscan2
- LRP1B | c.2577A>T p.Q859H | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV63341545, COSV63341769; called by muse, mutect2, varscan2
- LRP1B | c.1464C>G p.H488Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.113); catalogued as COSV101260227; called by muse, mutect2, varscan2
- LRP1B | c.336T>A p.H112Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV101260228; called by muse, mutect2
- LRP2 | c.3410G>A p.G1137E | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99790033; called by muse, mutect2, varscan2
- LRP4 | c.2053A>G p.M685V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV101066839; called by muse, mutect2
- LRP4 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.719); catalogued as COSV101066840; called by muse, mutect2, varscan2
- LRP6 | c.2228T>C p.V743A | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1450722002, COSV99744337; called by muse, mutect2
- LRRC31 | c.998T>C p.V333A | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.245); catalogued as COSV99247035; called by muse, mutect2, varscan2
- LRRC4C | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV53439652; called by muse, mutect2, varscan2
- LRRC4C | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99539531; called by muse, mutect2, varscan2
- LRRIQ1 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV101277722; called by muse, mutect2, varscan2
- LTN1 | c.3193C>T p.R1065C | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs201599162; called by muse, mutect2, varscan2
- LYRM7 | c.289T>G p.C97G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as COSV101041666; called by muse, mutect2, varscan2
- LYST | c.11386A>G p.S3796G | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs1355800709, COSV101090192; called by muse, mutect2
- MACROD2 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99442174; called by muse, mutect2, varscan2
- MAGEB16 | c.566C>G p.T189S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV101303329, COSV67874722; called by muse, mutect2, varscan2
- MANSC1 | c.614A>C p.Q205P | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV101115904; called by muse, mutect2
- MAP3K1 | c.1834A>T p.S612C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV101267099; called by muse, mutect2, varscan2
- MAP3K14 | c.2543G>T p.R848L | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.03); catalogued as COSV59304377; called by muse, mutect2, varscan2
- MAP3K4 | c.3550C>T p.R1184W | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1277040076, COSV100815651; called by muse, mutect2, varscan2
- MCAT | c.707G>T p.R236M | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99295768; called by muse, mutect2
- MCF2L2 | c.605C>G p.A202G | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100193801; called by muse, mutect2, varscan2
- MED21 | c.292C>A p.H98N | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV99282095; called by muse, mutect2
- METTL21C | c.423T>A p.D141E | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99940136; called by muse, mutect2, varscan2
- MID1IP1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100423801; called by muse, mutect2, varscan2
- MLLT1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.073); catalogued as rs185592757, COSV53130884; called by muse, mutect2, varscan2
- MMAB | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 28/137 reads (20%) | catalogued as COSV99904650; called by muse, mutect2, varscan2
- MME | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100852519, COSV64709539; called by muse, mutect2, varscan2
- MMEL1 | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.118); catalogued as COSV99984403; called by muse, mutect2, varscan2
- MMP13 | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 37/879 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555017381, COSV99506814; called by muse, mutect2
- MMP2 | c.1631C>A p.S544* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV54602948, COSV99528232; called by muse, mutect2, varscan2
- MMRN1 | c.1575G>T p.Q525H | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99307713; called by muse, mutect2, varscan2
- MNX1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs1364685705, COSV99429799; called by muse, mutect2
- MOGAT2 | c.651G>T p.G217= | Splice Region (SNP) | VAF 10/67 reads (15%) | catalogued as COSV99549712; called by muse, mutect2, varscan2
- MON1B | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.754); catalogued as COSV99941563, COSV99941843; called by muse, mutect2, varscan2
- MPP6 | c.1597T>C p.W533R | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99757813; called by muse, mutect2, varscan2
- MRGPRX3 | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as COSV101283581, COSV66933987; called by muse, mutect2
- MRPL49 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as COSV99589267; called by muse, mutect2, varscan2
- MRPS33 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.033); catalogued as rs750148841, COSV61341846; called by muse, mutect2, varscan2
- MSX1 | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV101235754; called by muse, mutect2, varscan2
- MTF2 | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100940180; called by muse, mutect2, varscan2
- MTR | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757429726, COSV63966998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTRF1 | c.870+2T>C p.X290_splice | Splice Site (SNP) | VAF 24/94 reads (26%) | catalogued as COSV101067579; called by muse, varscan2
- MUC16 | c.36535T>A p.Y12179N | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV101201373; called by muse, mutect2, varscan2
- MUC16 | c.24475A>G p.T8159A | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as rs1189080894, COSV101201374; called by muse, mutect2, varscan2
- MUC16 | c.6298G>T p.A2100S | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV101201377; called by muse, mutect2, varscan2
- MUC16 | c.4622C>A p.T1541K | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV101201378; called by muse, mutect2, varscan2
- MUC5B | c.11021C>A p.T3674N | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs570186533, COSV101500707; called by muse, mutect2, varscan2
- MYBPH | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV99704715; called by muse, mutect2, varscan2
- MYCBP2 | c.707T>C p.L236S (on ENST00000357337; = p.L274S on NM_015057.5) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.404); catalogued as COSV100631672; called by muse, mutect2, varscan2
- MYH8 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101238706; called by muse, mutect2, varscan2
- MYPN | c.2342A>G p.Q781R | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV100590538; called by muse, mutect2, varscan2
- NBAS | c.4384A>G p.T1462A | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV99871426; called by muse, mutect2, varscan2
- NBN | c.1638A>T p.R546S | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV99620020; called by muse, mutect2, varscan2
- NBN | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55373271, COSV99620023; called by muse, mutect2, varscan2
- NCAM1 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV100378476; called by muse, mutect2
- NCAPG | c.1259G>A p.R420K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV99266154; called by muse, mutect2, varscan2
- NCKAP1 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs774173976, COSV62940734, COSV62942508; called by muse, mutect2
- NDN | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs1454287617, COSV59359037; called by muse, mutect2
- NDUFS5 | c.99C>G p.C33W | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV100880480, COSV65892476; called by muse, mutect2, varscan2
- NELL2 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV100420639; called by muse, mutect2, varscan2
- NGF | c.101A>G p.Q34R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101049666; called by muse, mutect2, varscan2
- NLRP11 | c.2432G>T p.C811F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100789803; called by muse, mutect2, varscan2
- NLRP12 | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100145825, COSV60743700; called by muse, mutect2, varscan2
- NLRP14 | c.2798A>T p.D933V | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.559); catalogued as COSV100205392; called by muse, mutect2, varscan2
- NOTCH1 | c.5810G>A p.R1937H | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53086283; called by muse, mutect2, varscan2
- NPC1L1 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56931943, COSV99213385; called by muse, mutect2, varscan2
- NPFFR2 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100440870, COSV100441204; called by muse, mutect2, varscan2
- NPHS1 | c.59-1G>A p.X20_splice | Splice Site (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100800242; called by muse, mutect2
- NR2F1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59067601; called by muse, mutect2, varscan2
- NRDE2 | c.1134G>T p.Q378H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100583626; called by muse, mutect2
- NRF1 | c.1380G>C p.Q460H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV99782175; called by muse, mutect2, varscan2
- NSD2 | c.2188T>C p.C730R | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100373845; called by muse, mutect2
- NSUN5 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53091855; called by muse, mutect2
- NUMA1 | c.5206A>G p.S1736G | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100672430; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 11/94 reads (12%) | catalogued as rs780417788; called by mutect2, varscan2
- NXPE1 | c.652A>G p.T218A (on ENST00000424269; = p.T76A on NM_152315.5) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.06); catalogued as COSV99320948; called by muse, mutect2, varscan2
- OBSL1 | c.850C>A p.R284S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV54714810, COSV99217414; called by muse, mutect2, varscan2
- OLFML2B | c.1531G>T p.G511W | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54195923, COSV99668861; called by muse, mutect2, varscan2
- OR10Q1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs879268380, COSV57469880; called by muse, mutect2, varscan2
- OR10W1 | c.918G>T p.*306Yext*? | Nonstop Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as COSV101223784; called by muse, mutect2, varscan2
- OR1A2 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV101126384; called by muse, mutect2, varscan2
- OR2A12 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.114); catalogued as COSV101283202; called by muse, mutect2, varscan2
- OR2M5 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 60/489 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100822871; called by muse, mutect2, varscan2
- OR2T34 | c.667T>C p.Y223H | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758331266, COSV100170526; called by muse, mutect2
- OR2T34 | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100170528; called by muse, mutect2, varscan2
- OR2W1 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV101013939; called by muse, mutect2
- OR2Z1 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs373819151; called by muse, mutect2, varscan2
- OR4A16 | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.029); catalogued as COSV100125386; called by muse, mutect2
- OR4C46 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100060940, COSV60221458; called by muse, mutect2, varscan2
- OR4D9 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs760048609, COSV61434978; called by muse, mutect2, varscan2
- OR4K15 | c.355G>C p.D119H (on ENST00000305051; = p.D95H on NM_001005486.1) | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as COSV100521143; called by muse, mutect2, varscan2
- OR51E1 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.068); catalogued as COSV101211547, COSV67809313; called by muse, mutect2, varscan2
- OR51F1 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as COSV100598897; called by muse, mutect2, varscan2
- OR52N2 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 5/95 reads (5%) | catalogued as COSV100396117, COSV100396217; called by muse, mutect2
- OR52R1 | c.559G>T p.V187L | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV100617791; called by muse, mutect2
- OR52R1 | c.557C>G p.A186G | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.958); catalogued as COSV100617792; called by muse, mutect2
- OR56A1 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100360536; called by muse, mutect2, varscan2
- OR56B1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as rs1335393594, COSV100402514, COSV100402720; called by muse, mutect2, varscan2
- OR56B4 | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV100337691; called by muse, mutect2, varscan2
- OR5B12 | c.137T>G p.L46W | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100222538; called by muse, mutect2, varscan2
- OR5L1 | c.306C>A p.Y102* | Nonsense Mutation (SNP) | VAF 7/167 reads (4%) | catalogued as rs947136669; called by muse, mutect2
- OR8G1 | c.23del p.S8* | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as COSV58380984; called by mutect2, pindel, varscan2
- OR8H3 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100539137; called by muse, mutect2
- OR8J3 | c.532T>C p.Y178H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100041003; called by muse, mutect2, varscan2
- OR8K5 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs773839594, COSV100537318; called by muse, mutect2, varscan2
- OR8U1 | c.686A>C p.H229P | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56416758; called by muse, varscan2
- OXSR1 | c.1562T>C p.F521S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100309614; called by muse, mutect2, varscan2
- PACRGL | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.472); catalogued as rs1260697355, COSV99764349; called by muse, mutect2, varscan2
- PACS1 | c.1039-2A>T p.X347_splice | Splice Site (SNP) | VAF 24/52 reads (46%) | catalogued as COSV100270517; called by muse, mutect2, varscan2
- PARP6 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99536353; called by muse, mutect2, varscan2
- PAX3 | c.992C>A p.P331H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60589425; called by muse, mutect2, varscan2
- PCBP3 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101234376, COSV68406613; called by muse, mutect2, varscan2
- PCDH10 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as rs1166212333, COSV99993065; called by muse, mutect2
- PCDH15 | c.4843T>C p.C1615R | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as COSV100226848; called by muse, mutect2, varscan2
- PCDH15 | c.4624A>G p.I1542V | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100226851; called by muse, mutect2, varscan2
- PCDH15 | c.1364C>T p.T455I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100226854; called by muse, varscan2
- PCDH17 | c.2657G>T p.S886I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100931481; called by muse, mutect2, varscan2
- PCDHB6 | c.638C>G p.A213G | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99170961, COSV99173543; called by muse, mutect2, varscan2
- PCDHB8 | c.1697T>A p.L566Q | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); catalogued as COSV99177316; called by muse, mutect2
- PCDHGC5 | c.1202A>T p.E401V | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as rs757900187, COSV99338966, COSV99342138; called by muse, mutect2, varscan2
- PCLO | c.4759A>T p.S1587C | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV100437094; called by muse, mutect2, varscan2
- PCLO | c.3218C>A p.P1073H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100437097; called by muse, mutect2
- PCNT | c.2060A>C p.E687A | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100855998; called by muse, mutect2, varscan2
- PCSK5 | c.1314G>T p.V438= | Splice Region (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100950602; called by muse, mutect2, varscan2
- PCYOX1L | c.1327C>G p.L443V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as COSV99199267; called by muse, mutect2, varscan2
- PDE6C | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.031); catalogued as COSV101008851; called by muse, mutect2, varscan2
- PDILT | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.416); catalogued as rs751918734, COSV100199796, COSV56702199; called by muse, mutect2, varscan2
- PDS5B | c.2533A>G p.K845E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.912); catalogued as COSV100221468; called by muse, mutect2, varscan2
- PDZRN3 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV99731817; called by muse, mutect2, varscan2
- PEAR1 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1005288151, COSV99442260; called by muse, mutect2, varscan2
- PFDN4 | c.205T>C p.Y69H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1420149565, COSV101004639; called by muse, mutect2
- PGBD2 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs146329960; called by muse, mutect2, varscan2
- PGK2 | c.1034G>T p.W345L | Missense Mutation (SNP) | VAF 112/226 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV100505671; called by muse, mutect2, varscan2
- PGK2 | c.478G>T p.V160F | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100505673, COSV59163424; called by muse, mutect2, varscan2
- PHTF1 | c.1274A>T p.H425L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV100760181; called by muse, mutect2, varscan2
- PI4K2A | c.1146T>A p.D382E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV101034343; called by muse, mutect2, varscan2
- PI4KA | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.45); catalogued as COSV99748344; called by muse, mutect2, varscan2
- PIK3C2B | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs1311002740, COSV100916211; called by muse, mutect2, varscan2
- PIK3C2G | c.3334C>A p.P1112T (on ENST00000676171; = p.P1071T on NM_004570.5) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56797304; called by muse, mutect2, varscan2
- PLAC8L1 | c.393+1G>A p.X131_splice | Splice Site (SNP) | VAF 8/25 reads (32%) | catalogued as rs1388260135, COSV100268782; called by muse, mutect2, varscan2
- PLEKHA7 | c.1502G>T p.R501L | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100850405; called by muse, mutect2, varscan2
- PLK1 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV100267443; called by muse, mutect2
- PLK1 | c.816+1G>T p.X272_splice | Splice Site (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100267444; called by muse, mutect2
- PLPPR4 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.121); catalogued as COSV100926757; called by muse, mutect2, varscan2
- PLXDC2 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101023240; called by muse, mutect2, varscan2
- PLXNA1 | c.5319G>T p.L1773F | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99303998; called by muse, mutect2
- PMF1 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV100196391; called by muse, mutect2, varscan2
- PMS1 | c.2495A>T p.Y832F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100575776; called by muse, mutect2, varscan2
- PNLDC1 | c.1100A>G p.H367R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99277828; called by muse, mutect2, varscan2
- PNO1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs745558390, COSV55152588; called by muse, mutect2, varscan2
- POU2F3 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99501487; called by muse, mutect2, varscan2
- PPFIA2 | c.1421C>A p.T474N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100335027; called by muse, mutect2, varscan2
- PPL | c.1877A>G p.E626G | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as COSV100631037; called by muse, mutect2
- PPP1CB | c.802G>C p.A268P | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99941951; called by muse, mutect2, varscan2
- PPP1R16B | c.751del p.H251Mfs*7 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | catalogued as COSV55376955; called by mutect2, pindel, varscan2
- PRAMEF2 | c.1025C>A p.A342D | Missense Mutation (SNP) | VAF 86/138 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV99535653; called by muse, varscan2
- PRKCH | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100273148; called by muse, mutect2, varscan2
- PRMT1 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.253); catalogued as COSV101212338; called by mutect2, varscan2
- PRPS1L1 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV101552954, COSV72649893; called by muse, mutect2, varscan2
- PRR16 | c.760A>T p.T254S (on ENST00000407149 / NM_001300783.2; = p.T231S on NM_016644.2) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101087857; called by muse, mutect2, varscan2
- PRSS12 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs537006274, COSV99628825; called by muse, mutect2, varscan2
- PSG9 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 62/326 reads (19%) | catalogued as rs781444423, COSV52485409, COSV99392539; called by muse, mutect2, varscan2
- PSKH2 | c.431A>G p.E144G | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99405373; called by muse, mutect2, varscan2
- PSMC4 | c.1144-1G>T p.X382_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99338418; called by muse, varscan2
- PTPRB | c.554C>A p.A185D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99718771; called by muse, mutect2, varscan2
- PTPRC | c.926A>T p.H309L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1279900525, COSV100723103; called by muse, mutect2, varscan2
- PTPRF | c.3344G>A p.R1115H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs780287442, COSV63443586; called by muse, mutect2, varscan2
- PUS7 | c.715A>G p.K239E | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100708637; called by muse, mutect2
- PYCARD | c.40A>G p.N14D | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.366); catalogued as COSV99910960; called by muse, mutect2, varscan2
- RAB32 | c.446A>G p.K149R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV100832425; called by muse, mutect2, varscan2
- RACGAP1 | c.1520A>G p.H507R | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100407936; called by muse, mutect2, varscan2
- RACGAP1 | c.883A>T p.I295F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100407937; called by muse, varscan2
- RAD50 | c.836A>C p.K279T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV99529539; called by muse, mutect2, varscan2
- RANBP3L | c.1397G>T p.*466Lext*25 | Nonstop Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV99684031; called by muse, mutect2, varscan2
- RASAL2 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100862877; called by muse, mutect2, varscan2
- RASGRF2 | c.2854C>T p.R952* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as rs1224172379, COSV54122607; called by muse, mutect2, varscan2
- RASGRP4 | c.1101C>G p.D367E | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99498803; called by muse, mutect2
- RBM43 | c.213dup p.V72Sfs*18 | Frame Shift Ins (INS) | VAF 20/104 reads (19%) | catalogued as rs746242773; called by mutect2, varscan2
- RC3H2 | c.2678T>G p.I893R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV100606000; called by muse, mutect2, varscan2
- RECK | c.2054dup p.N685Kfs*16 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | catalogued as rs935356864; called by mutect2, varscan2
- RELN | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58992959; called by muse, mutect2, varscan2
- RHPN2 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs760951199, COSV99578221; called by muse, mutect2, varscan2
- RIC3 | c.610A>C p.I204L (on ENST00000309737 / NM_001206671.4; = p.I203L on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100112313; called by muse, mutect2, varscan2
- RNF133 | c.122A>T p.Y41F | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV100411740; called by muse, mutect2
- RNF20 | c.1533A>G p.T511= | Splice Region (SNP) | VAF 46/188 reads (24%) | catalogued as COSV101206577; called by muse, mutect2, varscan2
- RNF216 | c.1105C>T p.R369C (on ENST00000425013 / NM_207116.3; = p.R426C on NM_207111.4) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs777995180, COSV101111378; called by muse, mutect2, varscan2
- RP1L1 | c.1127T>C p.F376S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV101223563; called by muse, mutect2
- RTP2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/156 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as COSV100832999; called by muse, mutect2
- RYR2 | c.2929A>C p.K977Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100772587; called by muse, mutect2
- RYR2 | c.2931G>T p.K977N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100768759; called by muse, mutect2
- RYR2 | c.7036G>T p.A2346S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100772590; called by muse, mutect2, varscan2
- RYR3 | c.1566A>T p.K522N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV101214245; called by muse, mutect2
- SAGE1 | c.1452T>G p.I484M | Missense Mutation (SNP) | VAF 68/95 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV100187825; called by muse, mutect2, varscan2
- SAMD3 | c.278A>G p.D93G | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.04); catalogued as COSV100148403; called by muse, mutect2, varscan2
- SAMSN1 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99582363; called by muse, mutect2, varscan2
- SASH1 | c.3692T>G p.L1231R | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100821407; called by muse, mutect2, varscan2
- SATB1 | c.236T>C p.V79A | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100113431; called by muse, mutect2, varscan2
- SCAF11 | c.4382dup p.N1461Kfs*28 | Frame Shift Ins (INS) | VAF 26/164 reads (16%) | catalogued as rs1351378214; called by mutect2, varscan2
- SCN10A | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV101479515, COSV71861001; called by muse, mutect2, varscan2
- SCN2A | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.871); catalogued as COSV51850968, COSV99333249; called by muse, mutect2, varscan2
- SCN2B | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200264107; called by muse, mutect2, varscan2
- SEPTIN11 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.036); catalogued as rs774260132, COSV53583902; called by muse, mutect2, varscan2
- SERINC3 | c.1053T>C p.S351= | Splice Region (SNP) | VAF 14/101 reads (14%) | catalogued as COSV99667967; called by muse, mutect2, varscan2
- SERPINB10 | c.806C>A p.T269N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as rs201748994, COSV99449663; called by muse, mutect2, varscan2
- SFXN3 | c.606A>G p.R202= | Splice Region (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99827578; called by muse, mutect2
- SGO2 | c.2425A>G p.R809G | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV100764790; called by muse, mutect2, varscan2
- SIAH2 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV100469427; called by muse, mutect2, varscan2
- SIK3 | c.1942T>C p.Y648H (on ENST00000445177 / NM_001366686.2; = p.Y606H on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99408726; called by muse, mutect2, varscan2
- SIPA1L1 | c.315C>G p.C105W | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV100665516; called by muse, mutect2, varscan2
- SLAMF9 | c.312T>G p.D104E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100928185; called by muse, mutect2
- SLC13A4 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs770895655, COSV100818941; called by muse, mutect2, varscan2
- SLC15A1 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100918243; called by muse, mutect2, varscan2
- SLC16A6 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1333529411, COSV100517389; called by muse, mutect2
- SLC22A9 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99655336; called by muse, mutect2, varscan2
- SLC25A52 | c.125A>T p.K42M (on ENST00000672005; = p.K32M on NM_001034172.4) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99329797; called by muse, mutect2, varscan2
- SLC26A2 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs752568963, COSV99640374; called by muse, mutect2, varscan2
- SLC28A3 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100883329; called by mutect2, varscan2
- SLC28A3 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV100883331; called by muse, mutect2, varscan2
- SLC36A4 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100419454; called by muse, mutect2, varscan2
- SLC4A3 | c.3447G>T p.K1149N | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV99813166; called by muse, mutect2
- SLC5A7 | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50890131; called by muse, mutect2, varscan2
- SLC6A2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.01); catalogued as rs1352240042, COSV99574512; called by muse, mutect2, varscan2
- SLC9A1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56057260; called by muse, mutect2, varscan2
- SLC9B2 | c.1591G>T p.G531* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100294278; called by muse, mutect2, varscan2
- SLFN13 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.055); catalogued as COSV99540329; called by muse, mutect2, varscan2
- SLITRK1 | c.1807G>T p.G603W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as rs1199936878, COSV101000013; called by muse, mutect2, varscan2
- SLITRK1 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1212752482, COSV101000044; called by muse, mutect2, varscan2
- SLITRK4 | c.1415T>C p.M472T | Missense Mutation (SNP) | VAF 68/106 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV100567498; called by muse, varscan2
- SLITRK6 | c.1786A>G p.T596A | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV101233287; called by muse, mutect2, varscan2
- SMAD2 | c.998-2A>T p.X333_splice | Splice Site (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100054019; called by muse, mutect2, varscan2
- SMAD4 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as COSV61687877; called by muse, mutect2, varscan2
- SMCO3 | c.220A>G p.M74V | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99660855; called by muse, mutect2
- SNAP23 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs1378865436, COSV51041077; called by muse, mutect2
- SOGA3 | c.1232A>G p.Y411C | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100847053; called by muse, mutect2
- SORT1 | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as COSV99861089; called by muse, mutect2, varscan2
- SOS2 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99366722; called by muse, mutect2
- SOX7 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs767362815, COSV100449166; called by muse, mutect2, varscan2
- SPG7 | c.1012G>A p.A338T (on ENST00000268704; = p.A345T on NM_003119.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368373840; called by muse, mutect2, varscan2
- SPG7 | c.1565C>T p.A522V (on ENST00000268704; = p.A529V on NM_003119.4) | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs748600162, COSV99244920; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SPOCK1 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs748284037, COSV99970660; called by muse, mutect2, varscan2
- SPON1 | c.1561A>T p.M521L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100116575; called by muse, mutect2, varscan2
- SPTA1 | c.6839A>G p.Y2280C | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV63759350; called by muse, mutect2
- SRSF11 | c.1118+2T>C p.X373_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100918003; called by muse, mutect2, varscan2
- STARD10 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100600493; called by muse, mutect2
- STK31 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1253097391, COSV63459496; called by muse, mutect2, varscan2
- STK33 | c.197A>T p.N66I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100174451; called by muse, mutect2, varscan2
- STXBP5 | c.1151C>A p.P384H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99470884; called by muse, mutect2, varscan2
- SV2A | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553763641, COSV64965862; called by muse, mutect2
- SV2C | c.38A>C p.K13T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.244); catalogued as rs762793374, COSV100456762; called by muse, mutect2, varscan2
- SVIL | c.2247-2A>G p.X749_splice | Splice Site (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100881511; called by muse, mutect2
- SYNRG | c.1376A>G p.Q459R | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1163903159; called by muse, mutect2, varscan2
- TAF1C | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs759498955, COSV58986012; called by muse, mutect2, varscan2
- TAF1D | c.304A>T p.T102S | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV100127084; called by muse, mutect2
- TAF3 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 16/150 reads (11%) | catalogued as COSV100720458; called by muse, mutect2, varscan2
- TANC2 | c.3800A>G p.Y1267C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101267659; called by muse, mutect2, varscan2
- TARBP1 | c.4444A>G p.R1482G | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99242050; called by muse, mutect2, varscan2
- TAS1R1 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.017); catalogued as COSV100063462; called by muse, mutect2, varscan2
- TBX15 | c.1693A>C p.S565R (on ENST00000369429 / NM_001330677.2; = p.S459R on NM_152380.3) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV99254709; called by muse, mutect2, varscan2
- TBX4 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs765868170, COSV99540635; called by muse, mutect2, varscan2
- TCIRG1 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.493); catalogued as COSV99693591; called by muse, mutect2, varscan2
- TDO2 | c.814C>G p.R272G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.563); catalogued as COSV101539792, COSV72483902; called by muse, mutect2, varscan2
- TDRD9 | c.3870G>T p.R1290S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100175561; called by muse, mutect2, varscan2
- TECTA | c.564G>T p.W188C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99881380; called by muse, mutect2, varscan2
- TEKT3 | c.1163A>T p.D388V | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV58629722; called by muse, mutect2, varscan2
- TGS1 | c.1858A>G p.K620E | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV99485718; called by muse, mutect2
- THRB | c.23-2A>G p.X8_splice | Splice Site (SNP) | VAF 17/84 reads (20%) | catalogued as COSV100726224; called by muse, mutect2, varscan2
- THSD7B | c.2000C>T p.T667I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs372735350; called by muse, mutect2, varscan2
- TIAL1 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100958371; called by muse, mutect2, varscan2
- TIAM2 | c.1803+2T>C p.X601_splice | Splice Site (SNP) | VAF 14/75 reads (19%) | catalogued as COSV100019984; called by muse, mutect2, varscan2
- TIGD3 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776179323, COSV99361916; called by muse, mutect2, varscan2
- TLCD3A | c.289T>A p.C97S | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV100021588; called by muse, mutect2, varscan2
- TM6SF2 | c.175G>T p.V59F | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as rs371823523; called by muse, mutect2, varscan2
- TMCO1 | c.433A>C p.I145L (on ENST00000612311 / NM_001256164.1; = p.I94L on NM_019026.6) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100903204; called by muse, mutect2, varscan2
- TMEM132B | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100170768, COSV54755143; called by muse, mutect2, varscan2
- TMEM59 | c.899G>C p.R300T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV99329340; called by muse, mutect2, varscan2
- TMEM67 | c.1025A>T p.N342I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV100019828; called by muse, mutect2, varscan2
- TMPRSS12 | c.850G>T p.V284L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs1032513690, COSV101269159; called by muse, mutect2, varscan2
- TMTC1 | c.1747G>T p.D583Y (on ENST00000539277 / NM_001193451.2; = p.D475Y on NM_175861.3) | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99760836; called by muse, mutect2
- TMTC1 | c.1664G>A p.G555E (on ENST00000539277 / NM_001193451.2; = p.G447E on NM_175861.3) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99760840; called by muse, mutect2, varscan2
- TMTC1 | c.1567C>T p.L523F (on ENST00000539277 / NM_001193451.2; = p.L415F on NM_175861.3) | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99760842; called by muse, mutect2
- TMTC2 | c.1644T>A p.H548Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.1); catalogued as COSV100338800; called by muse, mutect2, varscan2
- TNN | c.3377G>A p.W1126* | Nonsense Mutation (SNP) | VAF 19/120 reads (16%) | catalogued as COSV53435823, COSV99512880; called by muse, mutect2, varscan2
- TNNT1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52573424; called by muse, mutect2, varscan2
- TOP2B | c.1951G>T p.D651Y (on ENST00000264331 / NM_001330700.2; = p.D646Y on NM_001068.3) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99980253; called by muse, mutect2, varscan2
- TOPORS | c.2504A>G p.N835S | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1361475613, COSV62116809; called by muse, mutect2
- TPPP | c.368T>A p.L123H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862890; called by muse, mutect2, varscan2
- TRAK1 | c.2242G>T p.G748C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565849; called by muse, mutect2, varscan2
- TRAPPC11 | c.2964G>C p.R988S | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100592024; called by muse, mutect2
- TRAV34 | c.306C>A p.S102R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs61740299; called by muse, mutect2, varscan2
- TRBC2 | c.424G>T p.V142F | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs1554512942; called by muse, mutect2, varscan2
- TRIM16 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs570022659, COSV60887587; called by muse, mutect2, varscan2
- TRNAU1AP | c.38A>G p.Y13C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100867974; called by muse, mutect2
- TRPC4 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.414); catalogued as COSV100157791; called by muse, mutect2, varscan2
- TRPM2 | c.1529T>C p.L510P | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100309271; called by muse, mutect2, varscan2
- TRPM6 | c.2932T>C p.F978L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV100666913; called by muse, mutect2, varscan2
- TRPM8 | c.1411C>A p.P471T | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100224489; called by muse, mutect2, varscan2
- TRPM8 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100224490; called by muse, mutect2, varscan2
- TRPV6 | c.2272G>A p.G758R | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.029); catalogued as rs757082631, COSV100844147; called by muse, mutect2
- TTC14 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.019); catalogued as rs748655551, COSV56009824; called by muse, mutect2, varscan2
- TTLL9 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201616223, COSV60596963; called by muse, mutect2, varscan2
- TTN | c.94721G>A p.R31574Q (on ENST00000591111; = p.R24150Q on NM_003319.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | PolyPhen probably damaging (0.992); catalogued as rs373182320; called by muse, mutect2, varscan2
- TTN | c.77149A>G p.K25717E (on ENST00000591111; = p.K18293E on NM_003319.4) | Missense Mutation (SNP) | VAF 37/129 reads (29%) | PolyPhen benign (0.043); catalogued as COSV100627578; called by muse, mutect2, varscan2
- TUBB2B | c.508A>G p.M170V | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99455615; called by muse, mutect2
- U2AF1L4 | c.587C>T p.P196L (on ENST00000412391; = p.R138* on NM_144987.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs146316690; called by muse, mutect2, varscan2
- UBE3B | c.3199C>G p.L1067V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100689094; called by muse, mutect2, varscan2
- UBR1 | c.229T>A p.Y77N | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV99317782; called by muse, mutect2, varscan2
- UGT1A10 | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV100762386; called by muse, mutect2, varscan2
- UGT2B28 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV100159022; called by muse, mutect2, varscan2
- UGT2B7 | c.1364A>G p.K455R | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as COSV100535309; called by muse, varscan2
- ULK4 | c.2151G>T p.M717I | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV100095032; called by muse, mutect2, varscan2
- UMODL1 | c.3653G>A p.R1218H (on ENST00000408910 / NM_001004416.2; = p.R1346H on NM_173568.3) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as rs768880257, COSV101252695, COSV68569828; called by muse, mutect2, varscan2
- UNC119B | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV100763516; called by muse, mutect2, varscan2
- USE1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99812616; called by muse, mutect2, varscan2
- USH2A | c.4306C>A p.P1436T | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100241744; called by muse, mutect2, varscan2
- USP1 | c.250A>G p.N84D | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100375423; called by muse, mutect2, varscan2
- USP2 | c.362G>A p.C121Y | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV99489939; called by muse, mutect2
- USP26 | c.1461dup p.G488Wfs*6 | Frame Shift Ins (INS) | VAF 37/75 reads (49%) | catalogued as rs761320003; called by mutect2, varscan2
- USP32 | c.821A>T p.K274M | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100342747; called by muse, mutect2, varscan2
- VPS13A | c.4448A>C p.D1483A | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.096); catalogued as COSV100653414; called by muse, mutect2, varscan2
- VPS13B | c.6508A>G p.K2170E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.192); catalogued as COSV100663403; called by mutect2, varscan2
- VPS13B | c.9527A>G p.D3176G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs764218807, COSV100663405; called by muse, mutect2, varscan2
- VPS13D | c.6543T>G p.D2181E | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV99169282; called by muse, mutect2, varscan2
- VRTN | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.321); catalogued as COSV56438987, COSV99832462; called by muse, mutect2, varscan2
- VTA1 | c.780G>A p.G260= | Splice Region (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100859261; called by muse, mutect2, varscan2
- VWF | c.2443-1G>T p.X815_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | catalogued as CS095178, COSV99780015; called by muse, mutect2
- WFS1 | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.906); catalogued as rs143055296, CM1515115, COSV99901167; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WNT10B | c.85A>C p.N29H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as COSV99976069; called by muse, mutect2
- XCR1 | c.285G>T p.W95C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58570698; called by muse, mutect2, varscan2
- XDH | c.1247A>G p.E416G | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1287340480, COSV101052445; called by muse, mutect2, varscan2
- XIRP2 | c.362C>T p.T121I (on ENST00000628543; = p.T296I on NM_152381.6) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99740989; called by muse, mutect2, varscan2
- XIRP2 | c.791C>A p.A264E (on ENST00000628543; = p.A439E on NM_152381.6) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as COSV99746802; called by muse, mutect2, varscan2
- XKR6 | c.1238G>A p.W413* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV58656374; called by muse, mutect2, varscan2
- YTHDC2 | c.3246G>T p.V1082= | Splice Region (SNP) | VAF 18/97 reads (19%) | catalogued as COSV99363824; called by muse, mutect2, varscan2
- YTHDC2 | c.3247G>T p.D1083Y | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV99363826; called by muse, mutect2, varscan2
- ZAN | c.1023G>A p.Q341= | Splice Region (SNP) | VAF 5/32 reads (16%) | catalogued as rs1175529971, COSV100770279; called by muse, mutect2
- ZBTB25 | c.133T>C p.F45L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101170752; called by muse, mutect2, varscan2
- ZBTB37 | c.838G>T p.G280C | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100774644; called by muse, mutect2
- ZDHHC24 | c.295T>C p.C99R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100130705; called by muse, mutect2, varscan2
- ZFHX3 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99214463; called by muse, mutect2, varscan2
- ZFHX4 | c.697C>G p.R233G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99266896; called by muse, mutect2, varscan2
- ZFHX4 | c.6633G>C p.Q2211H | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99266898; called by muse, mutect2, varscan2
- ZFHX4 | c.7682C>A p.P2561H | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV50660732, COSV99266900; called by muse, mutect2, varscan2
- ZFHX4 | c.9146A>G p.Y3049C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99264861; called by muse, mutect2, varscan2
- ZFHX4 | c.9802C>A p.P3268T | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as COSV99266906; called by muse, mutect2, varscan2
- ZHX1 | c.1979G>T p.S660I | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV99933854; called by mutect2, varscan2
- ZNF157 | c.1126C>A p.H376N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65660105; called by muse, mutect2, varscan2
- ZNF239 | c.1265A>G p.Q422R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100021908; called by muse, mutect2, varscan2
- ZNF320 | c.1222A>G p.T408A | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV101206928; called by muse, mutect2, varscan2
- ZNF365 | c.1172T>C p.I391T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.035); catalogued as rs900470575, COSV101237987; called by muse, mutect2
- ZNF366 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.981); catalogued as COSV100574446; called by muse, mutect2, varscan2
- ZNF37A | c.611A>T p.E204V | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV100697441; called by muse, mutect2, varscan2
- ZNF426 | c.24T>C p.H8= | Splice Region (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99465325; called by muse, mutect2
- ZNF536 | c.2517G>T p.R839S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100835786, COSV62824416; called by muse, mutect2, varscan2
- ZNF543 | c.1739A>G p.N580S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV100386914; called by muse, mutect2, varscan2
- ZNF574 | c.1630A>T p.T544S | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs763270366, COSV55905829, COSV99726471; called by muse, mutect2, varscan2
- ZNF585A | c.306G>A p.W102* (on ENST00000292841 / NM_001288800.2; = p.W47* on NM_152655.3) | Nonsense Mutation (SNP) | VAF 26/129 reads (20%) | catalogued as COSV99493522; called by muse, varscan2
- ZNF625 | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV100863533; called by muse, mutect2, varscan2
- ZNF711 | c.1572G>T p.M524I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV52159918, COSV99341536; called by muse, mutect2, varscan2
- ZNF711 | c.1858A>C p.K620Q | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.212); catalogued as COSV99341538; called by muse, mutect2
- ZNF777 | c.1975A>G p.T659A | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.27); catalogued as COSV99925357; called by muse, mutect2, varscan2
- ZSCAN4 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1203860317, COSV100552605; called by muse, mutect2, varscan2
- ZSWIM2 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54581425; called by muse, mutect2, varscan2
- ZYX | c.434A>T p.D145V | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100503820; called by muse, mutect2
- ABCB11 | c.2488dup p.R830Kfs*4 | Frame Shift Ins (INS) | VAF 16/89 reads (18%) | called by mutect2, pindel, varscan2
- ADAMTS3 | c.1665del p.S556Hfs*105 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- AMPD3 | c.680dup p.I228Hfs*6 (on ENST00000396553 / NM_001025389.2; = p.I237Hfs*6 on NM_000480.3) | Frame Shift Ins (INS) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- ASXL3 | c.5701C>A p.L1901I | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ATF7IP | c.1930-2A>G p.X644_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | called by mutect2, varscan2
- AXDND1 | c.1375dup p.W459Lfs*7 | Frame Shift Ins (INS) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- C12orf66 | c.894dup p.G299Wfs*11 | Frame Shift Ins (INS) | VAF 13/98 reads (13%) | called by mutect2, pindel, varscan2
- C1QTNF2 | c.10dup p.L4Pfs*14 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- C2CD3 | c.1429dup p.I477Nfs*12 | Frame Shift Ins (INS) | VAF 11/71 reads (15%) | called by mutect2, varscan2
- CCNB3 | c.539dup p.C181Vfs*5 | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | called by mutect2, pindel, varscan2
- CD5L | c.996dup p.H333Sfs*39 | Frame Shift Ins (INS) | VAF 12/118 reads (10%) | called by mutect2, pindel, varscan2
- CDC123 | c.902dup p.Y301* | Nonsense Mutation (INS) | VAF 16/116 reads (14%) | called by mutect2, pindel, varscan2
- CDC42BPG | c.3149G>A p.S1050N | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2
- CHRDL2 | c.909dup p.E304Rfs*22 | Frame Shift Ins (INS) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- CIART | c.121del p.A41Pfs*66 | Frame Shift Del (DEL) | VAF 37/187 reads (20%) | called by mutect2, pindel, varscan2
- COG2 | c.1651+7dup | Splice Region (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- CUBN | c.2743dup p.S915Ffs*3 | Frame Shift Ins (INS) | VAF 13/131 reads (10%) | called by mutect2, pindel, varscan2
- DEPDC1B | c.234dup p.F79Ifs*8 | Frame Shift Ins (INS) | VAF 35/137 reads (26%) | called by mutect2, varscan2
- DNAH8 | c.9786dup p.V3263Sfs*23 | Frame Shift Ins (INS) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- EPHA4 | c.1402A>G p.N468D | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- EPS8L2 | c.1442dup p.H482Tfs*21 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel
- FIGN | c.1087A>G p.N363D | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2
- GABRD | c.1241dup p.I415Hfs*14 | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- GOLGA3 | c.709dup p.T237Nfs*16 | Frame Shift Ins (INS) | VAF 32/190 reads (17%) | called by mutect2, varscan2
- GPR179 | c.859C>A p.P287T (on ENST00000621958; = p.P286T on NM_001004334.4) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HNF4A | c.1326del p.S443Lfs*76 | Frame Shift Del (DEL) | VAF 26/163 reads (16%) | called by mutect2, pindel, varscan2
- KCNJ9 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNV1 | c.1016T>C p.I339T | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2
- LAMA3 | c.9877A>T p.I3293F (on ENST00000313654 / NM_198129.4; = p.I1684F on NM_000227.6) | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- LLGL2 | c.2576A>G p.Y859C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- LMNB1 | c.1005_1006del p.R336Sfs*23 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by pindel, varscan2
- LYST | c.275dup p.A93Gfs*5 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- MED15 | c.2243dup p.L749Pfs*70 (on ENST00000263205 / NM_001003891.3; = p.L709Pfs*70 on NM_015889.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 10/86 reads (12%) | called by mutect2, pindel, varscan2
- MPEG1 | c.740_744del p.T247Kfs*5 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- MUC17 | c.13340dup p.N4447Kfs*5 | Frame Shift Ins (INS) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- NBPF26 | c.2344T>C p.W782R (on ENST00000620612; = p.W520R on NM_001351372.1) | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NEB | c.3384dup p.D1129Rfs*3 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- NSUN2 | c.1361_1362del p.Q454Pfs*16 | Frame Shift Del (DEL) | VAF 20/103 reads (19%) | called by mutect2, pindel, varscan2
- OR11H1 | c.480C>G p.F160L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.065); called by mutect2, varscan2
- OR5AS1 | c.896del p.N299Mfs*7 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- PCDHB6 | c.1341del p.A448Pfs*92 | Frame Shift Del (DEL) | VAF 37/126 reads (29%) | called by mutect2, varscan2
- PRAMEF19 | c.1259A>G p.D420G | Missense Mutation (SNP) | VAF 66/437 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PTPRC | c.3803dup p.E1269Rfs*5 | Frame Shift Ins (INS) | VAF 17/128 reads (13%) | called by mutect2, pindel, varscan2
- PTPRJ | c.349_350del p.T117Wfs*7 | Frame Shift Del (DEL) | VAF 5/60 reads (8%) | called by mutect2, pindel
- RPTOR | c.3297dup p.A1100Cfs*2 | Frame Shift Ins (INS) | VAF 26/185 reads (14%) | called by mutect2, pindel, varscan2
- SKIDA1 | c.2550dup p.P851Sfs*24 | Frame Shift Ins (INS) | VAF 7/61 reads (11%) | called by mutect2, pindel, varscan2
- SLC12A2 | c.2259dup p.P754Tfs*35 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- SLC19A1 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.606); called by muse, mutect2
- SLC7A4 | c.1111A>G p.T371A | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2
- SPRED1 | c.234del p.D79Tfs*42 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- SRP68 | c.122dup p.N41Kfs*17 | Frame Shift Ins (INS) | VAF 44/250 reads (18%) | called by mutect2, pindel, varscan2
- SRPRB | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.131); called by muse, mutect2
252 further variants in this file (6 protein-altering or splice-affecting, 228 silent, 18 other) are not listed here.
